CPTAC case C3N-04382 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/80327e65-e924-4293-82b5-bd538b5910bf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1970; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 47.9 years (17,484 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IB; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,130 days (3.1 years); Progression or recurrence: yes; Days to last follow up: 1,130 days (3.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm (a second GDC size field records 4.6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 9; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 286 days; Disease response: With Tumor.
- Days to follow up: 621 days (1.7 years); Disease response: With Tumor.
- Days to follow up: 1,130 days (3.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 208 days.
- Days to follow up: 1,130 days (3.1 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 68.04 kg; Height: 157.48 cm; BMI: 27.43.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 24; Cigarettes per day: 20; Tobacco smoking onset year: 1993; Tobacco smoking quit year: 2017; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 24.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04382-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 156 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04382-22: Section location: Right Middle Lobe; Percent tumor nuclei: 70; Percent necrosis: 15.
- Sample C3N-04382-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 198 mg; Time between excision and freezing: 31 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-04382-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 36 days; Method of sample procurement: Blood Draw.
